Somatic mutation profile of tumor specimen TCGA-G9-6379-01A (aliquot TCGA-G9-6379-01A-11D-A31L-08) from TCGA case TCGA-G9-6379, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.8 years (25,126 days).
Specimen TCGA-G9-6379-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d159278-8b1e-4b14-a1f2-adab462b63e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6379-10A (Blood Derived Normal), aliquot TCGA-G9-6379-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55d8f962-6dd5-4875-a220-5c0ea6773c4a

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 1, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.116T>A p.M39K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55955539; called by muse, mutect2, varscan2
- ATP10B | c.1918A>G p.T640A | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as COSV59157216; called by muse, mutect2
- CCDC112 | c.285A>T p.E95D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV65473505; called by muse, mutect2, varscan2
- HHIP | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56841049; called by muse, mutect2, varscan2
- KCNH5 | c.458C>A p.T153K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV59765765; called by muse, mutect2, varscan2
- LZTS2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV64652173; called by muse, mutect2, varscan2
- MPEG1 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs781256309, COSV57090203; called by muse, mutect2
- OR4S2 | c.884C>A p.A295E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV56747489; called by muse, mutect2
- PIWIL1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV55348637; called by muse, mutect2, varscan2
- POM121L12 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV68692610; called by muse, mutect2, varscan2
- RP1L1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776560263, COSV61446208; called by muse, mutect2, varscan2
- SCN4A | c.4882G>A p.D1628N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1004398583, COSV71127632; called by muse, mutect2, varscan2
- SERPINB5 | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66975733; called by muse, mutect2, varscan2
- SLC14A2 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as COSV54910802; called by muse, mutect2, varscan2
- SLC9C2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs775523749, COSV100876690, COSV100876800; called by muse, mutect2, varscan2
- STAT3 | c.1826G>C p.R609T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV52889607; called by muse, mutect2, varscan2
- TSPY2 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV57837021, COSV57837142; called by muse, mutect2, varscan2
- MIS18BP1 | c.779_783del p.T260Kfs*13 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel*, varscan2
- DIO1 | c.144G>A p.T48= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs780327542, COSV50777207; called by muse, mutect2, varscan2
- GTF2F1 | c.417C>G p.P139= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs749788471, COSV66726286; called by muse, mutect2, varscan2
- SP1 | c.1647C>G p.G549= (on ENST00000327443 / NM_138473.3; = p.G542= on NM_003109.1) | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV59403970; called by muse, mutect2, varscan2
- TTC7A | c.2043C>T p.A681= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs777962946, COSV55412829; called by muse, mutect2, varscan2
- VPS11 | c.751C>A p.R251= (on ENST00000620429; = p.R795= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV56185998; called by muse, mutect2
- CCDC144B | n.437C>T | RNA (SNP) | VAF 14/263 reads (5%) | catalogued as rs758968986; called by muse, mutect2
- OR10Q1 | c.*2G>A | 3'UTR (SNP) | VAF 45/274 reads (16%) | catalogued as COSV100372434; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4411A>G | Intron (SNP) | VAF 18/102 reads (18%) | catalogued as COSV58139973; called by muse, mutect2, varscan2
